Somatic mutation profile of tumor specimen TCGA-GV-A3JV-01A (aliquot TCGA-GV-A3JV-01A-11D-A21Z-08) from TCGA case TCGA-GV-A3JV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.4 years (24,243 days).
Specimen TCGA-GV-A3JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4039e80-f6f7-40cf-b5bd-59b1a5606082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A3JV-10B (Blood Derived Normal), aliquot TCGA-GV-A3JV-10B-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93ff8782-2ea1-4c5d-a1fd-5524a498ee71

The open-access MAF lists 126 somatic variants for this specimen: 90 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 28, Nonsense Mutation 7, Intron 3, Frame Shift Ins 2, Splice Site 2, Splice Region 2, 5'Flank 2, In Frame Ins 1, 3'Flank 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC9A3 | c.932+1G>A p.X311_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as rs144524702; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201224904, COSV62788933; called by muse, mutect2, varscan2
- ACTRT3 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.5); catalogued as rs1560579726, COSV57753769; called by muse, mutect2
- ADAMTS7 | c.2613G>T p.Q871H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV66305918; called by muse, mutect2, varscan2
- ADGRE5 | c.1045C>T p.P349S (on ENST00000242786 / NM_078481.4; = p.P256S on NM_001784.5) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54408359; called by muse, mutect2, varscan2
- ALDH8A1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 20/771 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640218; called by muse, mutect2
- ARID1A | c.4087C>T p.Q1363* | Nonsense Mutation (SNP) | VAF 142/252 reads (56%) | catalogued as COSV61381868; called by muse, varscan2
- ATF7IP | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.914); catalogued as COSV53766444; called by muse, mutect2, varscan2
- C11orf16 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.187); catalogued as COSV58166477; called by muse, mutect2, varscan2
- CACNA1G | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768796872, COSV61720364; called by muse, mutect2, varscan2
- CCDC78 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs369344548, COSV52400793; called by muse, mutect2, varscan2
- CDHR5 | c.2100G>A p.P700= (on ENST00000358353 / NM_001171968.2; = p.P706= on NM_021924.5) | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as rs763435731, COSV57641454; called by muse, mutect2, varscan2
- CGNL1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 75/274 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs772375615, COSV55563697; called by muse, mutect2, varscan2
- CHEK1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV54022204; called by muse, mutect2, varscan2
- CLCN4 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 130/169 reads (77%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66465197; called by muse, mutect2, varscan2
- CLCN6 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1303558451, COSV56737984; called by muse, mutect2, varscan2
- CSMD3 | c.2509C>T p.P837S (on ENST00000297405 / NM_001363185.1; = p.P733S on NM_052900.3) | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52105578; called by muse, mutect2
- CYP2A6 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV56533766; called by muse, mutect2, varscan2
- CYP3A7 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs778955930, COSV60480559; called by muse, mutect2, varscan2
- DCC | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.636); catalogued as COSV59085065; called by muse, mutect2, varscan2
- DDX24 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs769703503, COSV58211844; called by muse, mutect2, varscan2
- DPP8 | c.1892C>T p.T631I (on ENST00000341861 / NM_001320875.2; = p.T615I on NM_017743.6) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1463749943, COSV55676119; called by muse, mutect2, varscan2
- DPYD | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60075239; called by muse, mutect2, varscan2
- ELF3 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62837262; called by muse, mutect2, varscan2
- ESCO1 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568089599, COSV52518347; called by muse, mutect2
- FAM135A | c.2047C>T p.R683* (on ENST00000370479 / NM_001351599.1; = p.R470* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV52060218; called by muse, mutect2, varscan2
- FER1L6 | c.3966+2C>T p.X1322_splice | Splice Site (SNP) | VAF 39/166 reads (23%) | catalogued as COSV67548192; called by muse, mutect2, varscan2
- FSTL3 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV51261409; called by muse, varscan2
- FUT10 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756229709, COSV59449980; called by muse, mutect2, varscan2
- FZD3 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 88/175 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53534381; called by muse, mutect2, varscan2
- H1-4 | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs893449473, COSV56799874; called by muse, mutect2, varscan2
- HSP90AA1 | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV53487439; called by muse, varscan2
- KCNJ2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1555604000, COSV54660143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KDM3B | c.4382A>G p.D1461G | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58688102; called by muse, mutect2, varscan2
- KIAA0319 | c.583T>C p.F195L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV65496404; called by muse, mutect2, varscan2
- KRT7 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs766336452, COSV59329576; called by muse, mutect2, varscan2
- LEMD2 | c.1470G>C p.W490C | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53393180; called by muse, mutect2, varscan2
- LGI2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs1199976161, COSV66122342, COSV66124057; called by muse, mutect2, varscan2
- LYST | c.6305G>A p.R2102H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs201095810, COSV67703413; called by muse, mutect2, varscan2
- MAP3K1 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747288100, COSV68121804; called by muse, mutect2
- MAPK11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57996398; called by muse, mutect2, varscan2
- MEGF10 | c.2531G>T p.R844L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV57245118; called by muse, mutect2, varscan2
- MORC1 | c.2738C>G p.S913C | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV51714156; called by muse, mutect2, varscan2
- MROH5 | c.1992G>C p.L664F | Missense Mutation (SNP) | VAF 97/507 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV71300488; called by muse, mutect2, varscan2
- MTMR7 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV51663076; called by muse, mutect2, varscan2
- MUC16 | c.41176G>C p.E13726Q | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66689848; called by muse, mutect2, varscan2
- MUC17 | c.12301C>T p.R4101W | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs368040615, COSV60280196; called by muse, mutect2, varscan2
- MUC21 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs368730323; called by muse, mutect2, varscan2
- MYH6 | c.2166G>T p.Q722H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62447990; called by muse, mutect2, varscan2
- NIN | c.5203C>G p.L1735V (on ENST00000382041 / NM_182946.1; = p.L1022V on NM_016350.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV55380474; called by muse, mutect2, varscan2
- NOL8 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1187057914, COSV62634146; called by muse, mutect2, varscan2
- NOTCH1 | c.4451A>T p.N1484I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV53029383, COSV53081900; called by muse, mutect2, varscan2
- NTS | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs777196251, COSV55455476; called by muse, mutect2, varscan2
- PAPOLA | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.99); PolyPhen benign (0.065); catalogued as COSV53479124; called by muse, varscan2
- PCDHGA8 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs1301435337, COSV53900937; called by muse, mutect2, varscan2
- PCDHGB1 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV53900926; called by muse, mutect2, varscan2
- PDGFRA | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs765271720, COSV57264889, COSV57269575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1L1 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 74/473 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101005823, COSV65737369; called by muse, mutect2, varscan2
- PLGRKT | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56349081; called by muse, mutect2, varscan2
- POU4F1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65883762; called by muse, mutect2, varscan2
- PRCP | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57287460, COSV57291379; called by muse, varscan2
- PRKN | c.171G>A p.Q57= | Splice Region (SNP) | VAF 16/73 reads (22%) | catalogued as rs1554325642, COSV58202878; called by muse, mutect2, varscan2
- PTPN9 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.56); catalogued as COSV60722515; called by muse, mutect2, varscan2
- PXDNL | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV62478450; called by muse, mutect2, varscan2
- RNF5 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61247039; called by muse, mutect2, varscan2
- ROR1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761270555, COSV64283963, COSV64292121; called by muse, mutect2, varscan2
- RUSC2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs376434474, COSV100770766; called by muse, mutect2, varscan2
- SCAF4 | c.1357A>G p.R453G | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs1309978294, COSV54584315; called by muse, mutect2, varscan2
- SLC12A1 | c.1781C>A p.S594Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754682043, COSV66791881; called by muse, mutect2, varscan2
- SLC7A7 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1464272683, COSV53539351, COSV53541506; called by muse, mutect2, varscan2
- SPECC1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs144644210; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.209_210del p.A70Efs*157 | Frame Shift Del (DEL) | VAF 61/194 reads (31%) | catalogued as COSV50073524; called by mutect2, pindel, varscan2
- ST6GALNAC5 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 25/288 reads (9%) | PolyPhen probably damaging (0.992); catalogued as COSV59561992; called by muse, mutect2
- TP63 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV53196815; called by muse, mutect2, varscan2
- TPP2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as rs538453932, COSV65751030; called by muse, mutect2, varscan2
- TWNK | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as CM085293, COSV52966470; called by muse, mutect2, varscan2
- VPS13B | c.10300G>A p.E3434K | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.156); catalogued as COSV62133563; called by muse, mutect2, varscan2
- VWF | c.5990C>G p.A1997G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as COSV54611893; called by muse, mutect2, varscan2
- ZIC1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51550649; called by muse, mutect2, varscan2
- ZNF529 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.725); catalogued as COSV61899375; called by muse, mutect2, varscan2
- AARD | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- B3GALT4 | c.788C>A p.S263* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- BPIFB4 | c.1477_1479del p.K493del | In Frame Del (DEL) | VAF 23/143 reads (16%) | called by mutect2, pindel, varscan2
- DENND4B | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- ELF3 | c.436dup p.D146Gfs*15 | Frame Shift Ins (INS) | VAF 20/183 reads (11%) | called by mutect2, pindel, varscan2
- FRYL | c.4978C>T p.R1660* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- KRT19 | c.523_524dup p.R176Cfs*3 | Frame Shift Ins (INS) | VAF 59/180 reads (33%) | called by mutect2, pindel, varscan2
- MAP4 | c.2353_2355dup p.R785dup | In Frame Ins (INS) | VAF 75/275 reads (27%) | called by mutect2, pindel, varscan2
- SERAC1 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 32/96 reads (33%) | called by muse, mutect2, varscan2
- SFXN4 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- ABR | c.87C>T p.Y29= | Silent (SNP) | VAF 53/232 reads (23%) | catalogued as rs760840220, COSV56831941; called by muse, mutect2, varscan2
- AC018630.4 | c.129C>T p.F43= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV57391896; called by muse, mutect2, varscan2
- ADAMTS10 | c.720C>T p.Y240= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs782014221, COSV54352086; called by muse, mutect2, varscan2
- CFAP91 | c.714G>A p.V238= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1176412538, COSV56339186; called by muse, mutect2, varscan2
- CLMN | c.261G>A p.S87= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs189587823; called by muse, mutect2, varscan2
- CREBBP | c.5895G>A p.E1965= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- CRMP1 | c.1224C>T p.D408= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as rs377701143; called by muse, mutect2, varscan2
- DEFB126 | c.335G>A p.*112= | Silent (SNP) | VAF 44/283 reads (16%) | called by muse, mutect2, varscan2
- ESCO1 | c.114A>G p.K38= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs201017538, COSV52518357; called by muse, mutect2, varscan2
- IREB2 | c.2805C>T p.S935= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as rs1201675771, COSV51920740; called by muse, mutect2
- KL | c.2658G>A p.L886= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV66307878; called by muse, mutect2, varscan2
- MN1 | c.3018G>A p.T1006= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as rs1055257417, COSV56556051; called by muse, mutect2, varscan2
- NAV3 | c.483T>C p.A161= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV57062553; called by muse, mutect2, varscan2
- PCDHGA2 | c.1002C>T p.I334= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as COSV53896761; called by muse, mutect2, varscan2
- PLEKHG1 | c.276A>G p.R92= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV62045116; called by muse, mutect2, varscan2
- PTPRG | c.390C>T p.D130= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs189356599, COSV55629097; called by muse, mutect2, varscan2
- RALGAPB | c.51C>T p.G17= | Silent (SNP) | VAF 37/223 reads (17%) | catalogued as COSV53434491; called by muse, mutect2, varscan2
- SLC45A4 | c.531G>T p.G177= (on ENST00000517878 / NM_001286646.2; = p.G126= on NM_001080431.2) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV50133214; called by muse, mutect2
- SLC6A1 | c.54C>T p.S18= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV55113270; called by muse, mutect2, varscan2
- SLC6A18 | c.228C>T p.L76= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1422806855; called by muse, mutect2
- SSH3 | c.1650G>A p.L550= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV57383370; called by muse, mutect2, varscan2
- TAFA1 | c.165G>A p.K55= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV72037084; called by muse, mutect2, varscan2
- TBC1D1 | c.729G>A p.S243= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs777130926, COSV54714291; called by muse, mutect2, varscan2
- TIGD3 | c.648C>T p.L216= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV52887876, COSV52890165; called by muse, mutect2
- TOMM34 | c.717C>T p.V239= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV53838491, COSV53838784; called by muse, mutect2, varscan2
- TPO | c.1818C>T p.P606= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs148782927, COSV100222228, COSV61095146; called by muse, mutect2, varscan2
- ZNF414 | c.930G>A p.A310= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV55321127; called by muse, mutect2, varscan2
- ZNF786 | c.921A>G p.P307= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV60275016; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846817 A>G | 5'Flank (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+4937G>A | Intron (SNP) | VAF 10/54 reads (19%) | catalogued as COSV61225867; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055727 C>T | 3'Flank (SNP) | VAF 32/99 reads (32%) | catalogued as rs559153717; called by muse, mutect2, varscan2
- GCNT2 | c.926-35325C>G | Intron (SNP) | VAF 52/118 reads (44%) | catalogued as rs780473848, COSV53941133; called by muse, mutect2, varscan2
- NRP1 | c.1925-2331A>T | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- PCSK2 | c.*1C>T | 3'UTR (SNP) | VAF 14/75 reads (19%) | catalogued as rs778203328, COSV52742531; called by muse, mutect2, varscan2
- ZNF137P | n.1637G>C | RNA (SNP) | VAF 20/48 reads (42%) | catalogued as COSV60963168; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451333 G>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | catalogued as COSV56514238; called by muse, mutect2, varscan2
